Somatic mutation profile of tumor specimen 0DVXFA from CCDI case PBCNLG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 5.0 years (1,828 days).
Specimen 0DVXFA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4609384c-94fc-41fc-8779-025b0c04b217.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVXFS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/835a46bf-ed28-4be7-ba9f-a3b92412d686

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1, Nonsense Mutation 1, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FER1L6 | c.5042T>A p.L1681* | Nonsense Mutation (SNP) | VAF 52/1280 reads (4%) | called by muse, mutect2
- KPNA5 | c.329T>A p.L110Q | Missense Mutation (SNP) | VAF 25/912 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2
- THADA | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 36/1116 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, mutect2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 58/1575 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- TUBG2 | c.588G>A p.T196= | Silent (SNP) | VAF 120/486 reads (25%) | catalogued as rs150693772; called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 25/838 reads (3%) | called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 14/132 reads (11%) | called by muse, varscan2
